Somatic mutation profile of tumor specimen TARGET-10-PANVUU-09A (aliquot TARGET-10-PANVUU-09A-01D) from TARGET case TARGET-10-PANVUU, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,522 days).
Specimen TARGET-10-PANVUU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a1d9157-ae87-47a1-9d85-d18765a604cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANVUU-10A (Blood Derived Normal), aliquot TARGET-10-PANVUU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/398d1b92-e41c-4676-aae3-e6963b48de3a

The open-access MAF lists 14 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, 5'Flank 2, Nonsense Mutation 2, Silent 2, Intron 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASIC4 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.96); PolyPhen benign (0.145); catalogued as rs777402491, COSV61733953; called by muse, mutect2, varscan2
- IGFBP3 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs200568324, COSV99298512; called by muse, mutect2, varscan2
- NEUROD6 | c.409C>T p.R137* | Nonsense Mutation (SNP) | VAF 53/118 reads (45%) | catalogued as rs1183382119, COSV51770486; called by muse, mutect2, varscan2
- ONECUT1 | c.1226G>A p.R409H | Missense Mutation (SNP) | VAF 63/131 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs767975108, COSV59950547; called by muse, mutect2, varscan2
- VWA8 | c.445C>T p.R149* | Nonsense Mutation (SNP) | VAF 4/64 reads (6%) | catalogued as rs1010094785; called by muse, mutect2
- ATL3 | c.469_483delinsCAGA p.A157Qfs*7 | Frame Shift Del (DEL) | VAF 22/73 reads (30%) | called by pindel, varscan2*
- DCLK1 | c.1200T>A p.N400K | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HMCN2 | c.9994G>A p.V3332M | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.22); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- CHADL | c.1767G>A p.L589= | Silent (SNP) | VAF 30/41 reads (73%) | called by muse, mutect2, varscan2
- TDRD9 | c.2289G>A p.A763= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs1353238655, COSV59153377, COSV59155901; called by muse, mutect2
- EGFR | c.1881-590T>C | Intron (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- EML2 | chr19:45641624 G>A | 5'Flank (SNP) | VAF 46/119 reads (39%) | catalogued as rs780334028; called by muse, mutect2, varscan2
- LINC00840 | n.263C>A | RNA (SNP) | VAF 43/132 reads (33%) | called by muse, mutect2, varscan2
- TRMT10A | chr4:99563808 C>T | 5'Flank (SNP) | VAF 16/29 reads (55%) | called by muse, mutect2
